Gene-level copy-number profile of tumor specimen TCGA-ZF-AA54-01A from TCGA case TCGA-ZF-AA54, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Lateral wall of bladder; AJCC pathologic stage: Stage III; Tumor grade: High Grade; Age at diagnosis: 71.5 years (26,128 days).
Specimen TCGA-ZF-AA54-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BLCA.eca599f4-b84a-4c8f-91ba-1af69f21e8d7.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-ZF-AA54-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/0f8380b6-00b7-4fb7-8518-a8fdb2699c76

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 26; copy number 1: 464; copy number 2: 16,643; copy number 3: 22,641; copy number 4: 16,104; copy number 5: 2,580; copy number 6: 235; copy number 7: 725; copy number 9: 134; copy number 10: 218; copy number 13: 24; copy number 16: 17; copy number 33: 9.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-ZF-AA54-01A-11D-A390-01): tumor purity 0.43, ploidy 3.18, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 26 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:140,898,423–141,208,376, 4 genes: LRRC57P1, Y_RNA, RNU6-904P, RPS16P3.
- chr9:21,524,307–22,824,213, 21 genes (within-gene range 0–2): SNORD39, H3P30, KHSRPP1, RN7SL151P, MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2, AL157937.1, DMRTA1, LINC01239.
- chr9:22,747,700–22,748,234, 1 gene: CLIC4P1.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,127 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:38,383,838–43,931,165, 178 genes, copy number 10 (within-gene range 6–10) (broad region; genes not listed).
- chr2:97,355,059–101,024,032, 69 genes, copy number 7–33 (broad region; genes not listed).
- chr12:66,767–40,106,089, 880 genes, copy number 7–16 (within-gene range 6–16) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 457. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
